TARGET case TARGET-20-D49-Myeloid-GFP2 — Acute Myeloid Leukemia (TARGET-AML)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/f7337b54-e563-449c-8885-45529377ed30

Biospecimens (1 sample)
- Sample TARGET-20-D49-Myeloid-GFP2-85: Sample type: Next Generation Cancer Model; Tissue type: Normal.
